Somatic mutation profile of tumor specimen ALCH-B444-TTP1-A (aliquot ALCH-B444-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B444, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.0 years (25,206 days).
Specimen ALCH-B444-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7d79862-dcd2-4ca2-b956-95475c30599f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B444-NB1-A (Blood Derived Normal), aliquot ALCH-B444-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d8a22a8-39d1-4628-88b2-8bfa8032e06f

The open-access MAF lists 32 somatic variants for this specimen: 18 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 8, Intron 2, Splice Site 2, RNA 2, 5'Flank 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/850 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2
- ADRA2A | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV54528396, COSV99701617; called by muse, mutect2, varscan2
- ELOVL6 | c.629G>T p.C210F | Missense Mutation (SNP) | VAF 78/1192 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV56428694; called by muse, mutect2
- MAD1L1 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as rs749337220, COSV56226214; called by muse, mutect2, varscan2
- PAM | c.2585C>T p.S862L | Missense Mutation (SNP) | VAF 52/882 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs755377607, COSV57211563; called by muse, mutect2
- PTTG2 | c.261C>A p.S87R | Missense Mutation (SNP) | VAF 46/700 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.222); catalogued as rs541513996, COSV54725492; called by muse, mutect2
- ZNF536 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1279453916; called by muse, mutect2
- BIVM-ERCC5 | c.3317-1G>A p.X1106_splice | Splice Site (SNP) | VAF 29/891 reads (3%) | called by muse, mutect2
- EDEM2 | c.224C>G p.S75C | Missense Mutation (SNP) | VAF 17/302 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- H1-4 | c.149C>A p.A50D | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- LPCAT1 | c.1540T>G p.C514G | Missense Mutation (SNP) | VAF 18/472 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.351); called by muse, mutect2
- MED23 | c.3472-2A>T p.X1158_splice | Splice Site (SNP) | VAF 34/453 reads (8%) | called by muse, mutect2
- PCDHGA1 | c.1662C>A p.D554E | Missense Mutation (SNP) | VAF 25/512 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SKP2 | c.816G>T p.K272N | Missense Mutation (SNP) | VAF 25/566 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2
- STK11 | c.446dup p.V150Sfs*13 | Frame Shift Ins (INS) | VAF 24/279 reads (9%) | called by mutect2, pindel
- STXBP5L | c.3191T>A p.M1064K | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.339); called by muse, varscan2
- WDR41 | c.1343A>C p.K448T | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF133 | c.1515G>C p.Q505H (on ENST00000316358 / NM_001352454.2; = p.Q504H on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/295 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.739); called by muse, mutect2
- CDH13 | c.666C>A p.G222= | Silent (SNP) | VAF 36/510 reads (7%) | called by muse, mutect2
- CNGA3 | c.1680G>A p.S560= | Silent (SNP) | VAF 82/967 reads (8%) | catalogued as rs1207666489; called by muse, mutect2
- FBXO47 | c.141A>G p.L47= | Silent (SNP) | VAF 32/296 reads (11%) | called by mutect2, varscan2
- MYH13 | c.4842C>T p.D1614= | Silent (SNP) | VAF 39/524 reads (7%) | catalogued as rs1159605080, COSV52834189; called by muse, mutect2
- MYOM1 | c.2898T>G p.T966= | Silent (SNP) | VAF 18/326 reads (6%) | called by muse, mutect2
- PCDHGA10 | c.1995C>T p.T665= | Silent (SNP) | VAF 52/888 reads (6%) | catalogued as rs781724309, COSV54005188; called by muse, mutect2
- TEAD3 | c.1077G>T p.V359= | Silent (SNP) | VAF 17/124 reads (14%) | called by muse, mutect2, varscan2
- ZNF286A | c.570G>A p.K190= | Silent (SNP) | VAF 40/381 reads (10%) | called by muse, mutect2, varscan2
- C16orf87 | c.66+75C>T | Intron (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2
- DPY19L2P1 | n.386G>A | RNA (SNP) | VAF 38/1047 reads (4%) | called by muse, mutect2
- GNAS | c.*34G>C | 3'UTR (SNP) | VAF 21/498 reads (4%) | called by muse, mutect2
- MASP1 | c.1303+5314C>A | Intron (SNP) | VAF 48/534 reads (9%) | called by muse, mutect2
- STX4 | chr16:31033382 G>C | 5'Flank (SNP) | VAF 26/327 reads (8%) | called by muse, mutect2
- USP2-AS1 | n.103A>C | RNA (SNP) | VAF 24/506 reads (5%) | called by muse, mutect2
